Surgical pathology report (de-identified scan), TCGA case TCGA-MX-A663, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MSKCC, specimen TCGA-MX-A663-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]
DOB: [REDACTED]
Physician: [REDACTED]
CC:
Patient Address:

Accession #:
Service:
Date of Procedure:
Date of Receipt:
Date of Report:

....

Clinical Diagnosis & History:

Gastric adenocarcinoma in gastric remnant, gastrectomy for ulcer disease distant past.

Specimens Submitted:

- 1: Remnant gastrectomy with attached segment of transverse colon
- 2: Celiac lymph node
- 3: Omentum

DIAGNOSIS:

1. Remnant gastrectomy with attached segment of transverse colon:
Tumor Type:

Invasive adenocarcinoma

Lauren's Type:

Mixed [each component > 25%]

Histologic Grade:

Poorly differentiated

Tumor Involvement:

Pylorus with duodenum
Gastric remnant

Tumor Size:

The length is 5.4 cm
The width is 2.5 cm
The maximum thickness is 1 cm

Depth of Tumor Invasion:

Tumor invades the subserosa

Preexisting Polyp (at the site of the carcinoma):

Not identified

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Multicentricity:

Not identified

Peritoneum:

Not involved

Surgical Margins:

All are free of carcinoma and dysplasia

Adjacent Mucosa:

Gastric mucosa unremarkable

** Continued on next page **

IED-0-3

Adenocarcinoma NOS
8144/3

Site: Stomach NOS CK6.
JW 5/10/13

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

----- Page 2 of 4

Separate Polyps:

Not identified

Helicobacter Pylori:

Not identified

Lymph Nodes:

Number of nodes examined: 10

Number of lymph nodes with metastasis: 0

Tumor Staging (AJCC 7th Edition):

pT3 Tumor penetrates subserosal connective tissue without invasion of visceral peritoneum or adjacent structure

Lymph Nodes Staging (AJCC 7th Edition):

pN0 No regional lymph node metastasis

The final lymph node count is the sum of part 1-2 (0/15)

2. Lymph node, celiac; excision:
- Five benign lymph nodes (0/5)

3. Omentum; omentectomy:
- Benign adipose tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh and labeled "Long stitch = proximal, short = distal jejunum, remnant gastrectomy with attached segment of transverse colon". It consists of a segment of stomach that is anastomosed to a portion of small bowel measuring 8.3 cm in length and 3 cm in diameter. The stomach measures 8.8 cm in diameter at the proximal end and 8.8 x 7.0 x 3.5 cm overall. There is a long stitch at the proximal end and a short stitch at the distal of the jejunum end per the requisition. The specimen is opened to reveal a normally folded gastric mucosa with a firm, poorly defined, mass at the anastomosis site measuring 5.4 x 2.5 cm that is located 5.2 cm from the proximal stomach margin, 1.6 cm from the proximal small bowel margin and 4.5 cm from the distal small bowel margin. The remaining small bowel mucosa is brown and unremarkable.

Attached to the specimen, by a portion of adipose tissue, is a separate segment of colon measuring 5 cm in length and 3.2 cm in diameter. The colon segment is opened to reveal tan, unremarkable mucosa.

A portion of the mass is submitted for TPS. The greater and lesser curvature adipose tissue, pericolic and attached adipose tissue are palpated for lymph nodes. All identified lymph nodes are submitted entirely. Representative sections are submitted.

Summary of sections:

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #:
Physician:
Service:
Date of Report:

Page 3 of 4

RSM representative stomach margin
M mass (submitted entirely)
PJM Proximal jejunum margin with mass (perpendicular margin)
RPJM remaining proximal jejunum margin
DJM Distal jejunum margin
SC separate portion of colon, representative sections
LNG lymph nodes greater curvature
LNL lymph nodes lesser curvature
LN lymph nodes

2). The specimen is received in formalin, labeled "Celiac lymph node", and consists of three fatty lymph nodes ranging from 0.2 to 0.3 cm in greatest dimension. All identified lymph nodes and the remaining fibrofatty tissue is submitted.

Summary of sections:
LN - lymph nodes
RS - remaining fibrofatty tissue

3) The specimen is received fresh, labeled "Omentum". It consists of a 14.5 x 8.0 x 2.3 cm vascularized adipose tissue consistent with omentum, displaying minimal fibrous adhesion. Serial sectioning displays no discrete mass or lesion. Representative sections are submitted.

Summary of sections:
O Omentum, to include fibrous adhesions in block 1

Summary of Sections:
Part 1: Remnant gastrectomy with attached segment of transverse colon

Block	Sect.	Site	PCs
1		DJM	1
1		LN	3
2		LNG	6
1		LNL	4
5		M	5
1		PJM	1

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #:
Physician:
Service:
Date of Report:

Page 4 of 4

1 RPJM 2
1 RSM 1
1 SC 2

Part 2: Celiac lymph node

Block	Sect. Site	PCs
1	LN	3
2	RS	2

Part 3: Omentum

Block	Sect. Site	PCs
2	O	3

Procedures/Addenda:

Addendum

Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis

1. Remnant gastrectomy with attached segment of transverse colon:
- Immunostain for Her2-Neu is negative in tumor cells (0).

*** Report Electronically Signed Out ***
Signed out by

**** End of Report ****

Source: NCI Genomic Data Commons file 0cae41b5-dc9d-4ac0-9c3d-d24487397978 (TCGA-MX-A663.7C1CC92B-F649-403D-B995-A48491188E21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).